Somatic mutation profile of tumor specimen TCGA-BJ-A3PT-01A (aliquot TCGA-BJ-A3PT-01A-12D-A21Z-08) from TCGA case TCGA-BJ-A3PT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.8 years (18,903 days).
Specimen TCGA-BJ-A3PT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c31c2a6-a75b-4efa-a2a8-ed96543deba4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A3PT-10A (Blood Derived Normal), aliquot TCGA-BJ-A3PT-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/467aec94-66a1-4317-a21c-d97b8999d60d

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 94/288 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CELF2 | c.409G>A p.G137R (on ENST00000416382 / NM_001025077.3; = p.G144R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59972594; called by muse, mutect2, varscan2
- CHEK2 | c.1299C>G p.Y433* (on ENST00000382580 / NM_001005735.2; = p.Y390* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV60418950; called by muse, mutect2
- FRMPD4 | c.1710A>G p.I570M | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV66213777; called by muse, mutect2
- GEMIN5 | c.350G>T p.W117L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53559891; called by muse, mutect2, varscan2
- GON4L | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV55191959; called by muse, mutect2
- MCTP2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59143061; called by muse, mutect2
- OR4K5 | c.703A>C p.K235Q | Missense Mutation (SNP) | VAF 26/630 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60003182; called by muse, mutect2
- PDE1A | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.079); catalogued as COSV59520830; called by muse, mutect2, varscan2
- RAPGEF6 | c.1741G>T p.V581L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV57244463; called by muse, mutect2
- SP140 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV59448610; called by muse, mutect2
- PNCK | c.648C>T p.S216= (on ENST00000340888 / NM_001366975.1; = p.S299= on NM_001039582.3) | Silent (SNP) | VAF 61/207 reads (29%) | catalogued as rs940995640, COSV61743308; called by muse, mutect2, varscan2
